MMRF case MMRF_1686 — Multiple Myeloma CoMMpass Study (MMRF-COMMPASS)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Plasma Cell Tumors; Primary site: Hematopoietic and reticuloendothelial systems. Index date (day 0 for every day count below): first treatment.
https://portal.gdc.cancer.gov/cases/c7d6451a-8653-4fb8-a433-ba7e00047c8d

Demographics
Sex at birth: female; Race: white; Ethnicity: not hispanic or latino; Age at index: 37 years; Vital status: Alive.

Diagnoses (1)
1. Multiple myeloma: ICD-O-3 morphology code: 9732/3; Tissue or organ of origin: Bone marrow; Site of resection or biopsy: Bone marrow; Age at diagnosis: 38.0 years (13,869 days); ISS stage: I; Days to last known disease status: 1,192 days (3.3 years); Days to last follow up: 1,192 days (3.3 years).
   Treatment given: Therapeutic agents: Bortezomib + Cyclophosphamide + Dexamethasone; Regimen or line of therapy: First line of therapy; Days to treatment start: 1 day.
   Treatment given: Therapeutic agents: Melphalan; Regimen or line of therapy: First line of therapy; Days to treatment start: 224 days; Days to treatment end: 224 days.
   Treatment given: Treatment type: Stem Cell Transplantation, Autologous; Regimen or line of therapy: First line of therapy; Days to treatment start: 225 days; Days to treatment end: 225 days.

Molecular and laboratory tests (laboratory values one line per visit day; values rounded to 3 significant figures where GDC's unit conversion carried more)
- Day -17 (ECOG 1): M Protein 2.98 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 102 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.771 mg/dL; Immunoglobulin G 41.2 g/L; Immunoglobulin A 1.53 g/L; Immunoglobulin M 0.59 g/L; Beta 2 Microglobulin 2.82 µg/mL; Lactate Dehydrogenase 2.47 µkat/L; Hemoglobin 6.7 mmol/L; Leukocytes 7.4 ×10⁹/L; Absolute Neutrophil 4.3 ×10⁹/L; Platelets 329 ×10⁹/L; Creatinine 68.1 µmol/L; Blood Urea Nitrogen 3.93 mmol/L; Calcium 2.45 mmol/L; Albumin 42 g/L; Total Protein 9.8 g/dL; Glucose 4.79 mmol/L; C-Reactive Protein 0.89 mg/dL.
- Day 78 (ECOG 1): M Protein 1.97 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 33.5 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.116 mg/dL; Immunoglobulin G 22.4 g/L; Immunoglobulin A 0.63 g/L; Immunoglobulin M 0.31 g/L; Beta 2 Microglobulin 2 µg/mL; Lactate Dehydrogenase 2.32 µkat/L; Hemoglobin 7.01 mmol/L; Leukocytes 5.6 ×10⁹/L; Absolute Neutrophil 4.1 ×10⁹/L; Platelets 286 ×10⁹/L; Creatinine 53.9 µmol/L; Blood Urea Nitrogen 3.57 mmol/L; Calcium 2.25 mmol/L; Albumin 42 g/L; Total Protein 8.3 g/dL; Glucose 4.95 mmol/L.
- Day 191 (ECOG 0): M Protein 1.35 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 5.32 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.58 mg/dL; Immunoglobulin G 18.5 g/L; Immunoglobulin A 0.58 g/L; Immunoglobulin M 0.36 g/L; Beta 2 Microglobulin 1.11 µg/mL; Hemoglobin 7.19 mmol/L; Leukocytes 5.6 ×10⁹/L; Absolute Neutrophil 4.9 ×10⁹/L; Platelets 196 ×10⁹/L; Creatinine 55.7 µmol/L; Blood Urea Nitrogen 3.93 mmol/L; Calcium 2.43 mmol/L; Albumin 41 g/L; Total Protein 7.7 g/dL; Glucose 4.57 mmol/L.
- Day 281 (ECOG 0): M Protein 1.77 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 13.9 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.059 mg/dL; Immunoglobulin G 21.4 g/L; Immunoglobulin A 0.41 g/L; Immunoglobulin M 0.25 g/L; Lactate Dehydrogenase 2.9 µkat/L; Hemoglobin 7.13 mmol/L; Leukocytes 4 ×10⁹/L; Absolute Neutrophil 1.88 ×10⁹/L; Platelets 278 ×10⁹/L; Creatinine 53.9 µmol/L; Blood Urea Nitrogen 2.86 mmol/L; Calcium 2.35 mmol/L; Albumin 41 g/L; Total Protein 8 g/dL; Glucose 5.72 mmol/L.
- Day 351 (ECOG 0): M Protein 0.68 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 6.28 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.08 mg/dL; Immunoglobulin G 10.4 g/L; Immunoglobulin A 0.52 g/L; Immunoglobulin M 0.34 g/L; Hemoglobin 6.88 mmol/L; Leukocytes 3.2 ×10⁹/L; Absolute Neutrophil 1.8 ×10⁹/L; Platelets 321 ×10⁹/L; Creatinine 66.3 µmol/L; Blood Urea Nitrogen 3.93 mmol/L; Calcium 2.08 mmol/L; Albumin 40 g/L; Total Protein 6.5 g/dL; Glucose 4.62 mmol/L.
- Day 443 (ECOG 1): Hemoglobin 6.57 mmol/L; Leukocytes 3.6 ×10⁹/L; Absolute Neutrophil 1.7 ×10⁹/L; Platelets 52 ×10⁹/L; Creatinine 61.9 µmol/L; Blood Urea Nitrogen 3.93 mmol/L; Calcium 2.35 mmol/L; Albumin 47 g/L; Total Protein 7.1 g/dL; Glucose 5.17 mmol/L.
- Day 527 (ECOG 1): M Protein 0.44 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 0.288 mg/dL; Immunoglobulin G 8.79 g/L.
- Day 793: M Protein 0.38 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 4.29 mg/dL; Immunoglobulin G 8.48 g/L.
- Day 856 (ECOG 1): M Protein 0.42 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 0.349 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.125 mg/dL; Immunoglobulin G 8.54 g/L; Immunoglobulin A 0.85 g/L; Immunoglobulin M 0.5 g/L; Hemoglobin 6.45 mmol/L; Leukocytes 9.3 ×10⁹/L; Absolute Neutrophil 6.5 ×10⁹/L; Platelets 232 ×10⁹/L; Creatinine 70.7 µmol/L; Blood Urea Nitrogen 3.57 mmol/L; Calcium 2.25 mmol/L; Albumin 43 g/L; Total Protein 6.7 g/dL; Glucose 4.68 mmol/L.
- Day 1,003: M Protein 0.42 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 0.262 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.382 mg/dL.
- Day 1,108: M Protein 0.41 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 0.242 mg/dL.
- Day 1,192: M Protein 0.38 g/dL; Immunoglobulin G 8.59 g/L; Immunoglobulin A 1.29 g/L; Immunoglobulin M 0.55 g/L; Hemoglobin 7.44 mmol/L; Leukocytes 7 ×10⁹/L; Absolute Neutrophil 4.6 ×10⁹/L; Platelets 315 ×10⁹/L; Creatinine 70.7 µmol/L; Blood Urea Nitrogen 2.86 mmol/L; Calcium 2.15 mmol/L; Albumin 41 g/L; Total Protein 6.5 g/dL; Glucose 5.45 mmol/L.

Other clinical attributes
- Day -17: Weight: 64 kg; Height: 165 cm.

Family history
- Relative with cancer history: yes; Relationship type: Paternal Grandfather; Relationship primary diagnosis: Lung Cancer; Relationship sex at birth: male.

Biospecimens (3 samples)
- Sample MMRF_1686_1_BM_CD138pos: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS; Days to sample procurement: -17 days.
- Sample MMRF_1686_1_PB_Whole: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS; Days to sample procurement: -17 days.
- Sample MMRF_1686_2_BM_CD138pos: Sample type: Recurrent Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Recurrence; Specimen type: Bone Marrow NOS; Days to sample procurement: 281 days.
